Surgical pathology report (de-identified scan), TCGA case TCGA-77-7142, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Prince Charles Hospital, specimen TCGA-77-7142-01A (Primary Tumor).

HISTORY

Lung cancer.

MACROSCOPIC

Two specimens received:

1: The specimen is labelled 'left upper lobe' and comprises a lobe of lung measuring 230 x 140 x 35 mm after formalin inflation. There is an area of roughening of the pleural surface on the medial aspect of the lobe anterior to the hilum measuring 40 mm in diameter. Several bullae are present at the apex where there is again some irregular pleural thickening and roughening. No obvious tumour is apparent on the pleural surface. Serial transverse slicing reveals an irregular pale tumour mass, 37 mm in greatest diameter, occupying the central portion of the superior part of the lobe. Tumour is at least 25 mm deep to the closest pleural surface. It is also at least 30 mm from the bronchial resection margin. Uninvolved lung parenchyma shows moderately severe emphysema. No satellite lesions are identified. [1A, peribronchial lymph node; 1B, bronchial resection margin; 1C-D, complete TS of tumour bisected; 1E, uninvolved parenchyma from apex; 1F, uninvolved parenchyma from lingula].

2: The specimen is labelled 'lymph node upper lobe' and comprises an irregular portion of fatty and connective tissue measuring 17 x 12 x 4 mm. [BIT after bisection, 2A].

MICROSCOPIC

1. Sections show a very poorly-differentiated squamous cell carcinoma. Tumour is growing as large nests and sheets of cells with central necrosis. Very focal but convincing keratinization is taking place. The lesion is located halfway between the pleura and the hilum and pleural invasion is not identified. There is no blood vessel invasion and no lymphatic permeation is seen. No perineural permeation is identified. The lesion is well clear of the bronchial resection margin. Peribronchial lymph nodes are showing sinus histiocytosis and contain some carbon pigment but metastases are absent. The adjacent lung shows prominent emphysema.

2. The sections show lymph node tissue in which there is sinus histiocytosis and carbon pigment but no evidence of tumour.

SUMMARY

Left upper lobe of lung and lymph nodes:

- 1: Poorly-differentiated squamous cell carcinoma; 37mm in maximal dimension;
- 2: No blood vessel, lymphatic or perineural invasion present;
- 3: No pleural invasion identified; clear of bronchial margin;
- 4: No lymph node metastases;
- 5: Pathological stage T2N0Mx.

T-28000 M-80703 P1-03000

cc Lung Cancer Registry

Source: NCI Genomic Data Commons file 804aa207-f349-4644-af7b-5afff85d53a1 (TCGA-77-7142.31535F27-9A8D-4B0A-B20C-10E183939711.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).